Somatic mutation profile of tumor specimen 0DV2RY from CCDI case PBCMEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.0 years (3,636 days).
Specimen 0DV2RY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0655c029-8dc9-45c5-b6d6-a8f87d9a39a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV2QW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5ee165b-6c1c-4bff-a937-9fe07d0b7e74

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Intron 2, 3'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4492C>T p.R1498* | Nonsense Mutation (SNP) | VAF 172/389 reads (44%) | catalogued as CM021084, COSV52113607; called by muse, mutect2, varscan2
- DCUN1D4 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 83/275 reads (30%) | catalogued as rs1320224880; called by muse, mutect2, varscan2
- EGR2 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV54348787; called by muse, mutect2, varscan2
- PALB2 | c.2243C>T p.T748I | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as rs762533408; called by muse, mutect2, varscan2
- ANKRD12 | c.1186dup p.T396Nfs*14 | Frame Shift Ins (INS) | VAF 142/402 reads (35%) | called by mutect2, varscan2
- CFTR | c.3692C>T p.S1231F | Missense Mutation (SNP) | VAF 215/561 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DMD | c.8486G>A p.S2829N | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IPO11 | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 191/491 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- LTN1 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 126/388 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- PALB2 | c.2242A>C p.T748P | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- AFDN | c.4947+41G>A | Intron (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- EMD | c.83-47G>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- GTSCR1 | n.31G>T | RNA (SNP) | VAF 75/320 reads (23%) | called by muse, mutect2, varscan2
- PPY | c.*35C>T | 3'UTR (SNP) | VAF 69/162 reads (43%) | catalogued as rs373710345; called by muse, mutect2, varscan2
